Gene-level copy-number profile of tumor specimen ALCH-B1L5-TTP1-A from ALCHEMIST case ALCH-B1L5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.3 years (25,306 days).
Specimen ALCH-B1L5-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a04f9691-da20-49ee-af46-3472443ae50e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1L5-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,254 have no estimate.
https://portal.gdc.cancer.gov/files/f5e2bb4c-5568-492e-830b-bcd7d162dbf2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 96; copy number 2: 58,099; copy number 3: 140; copy number 4: 19; copy number 5: 3; copy number 6: 3; copy number 7: 1; copy number 8: 1; copy number 9: 1; copy number 10: 4.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:18,516,344–18,524,935, 2 genes: GGTLC3, Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:135,802,985–135,803,075, 1 gene, copy number 6: MIR5692C1.
- chr7:74,773,962–74,789,376, 1 gene, copy number 6: NCF1.
- chr13:112,313,467–112,321,758, 1 gene, copy number 7: LINC01043.
- chr16:32,475,051–32,478,250, 1 gene, copy number 6: ABCD1P3.
- chr22:18,400,407–18,512,187, 4 genes, copy number 10: PPP1R26P3, FAM230A, AC023490.2, FAM247B.
- chr22:18,527,802–18,530,573, 1 gene, copy number 9: TMEM191B.
- chr22:18,623,339–18,719,341, 4 genes, copy number 5–8: SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4.

Autosomal genes at a single copy (total copy number 1): 96. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
